Somatic mutation profile of tumor specimen MMRF_2628_1_BM_CD138pos (aliquot MMRF_2628_1_BM_CD138pos_T1_KHS5U_L13300) from MMRF case MMRF_2628, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2628_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5348461a-0388-4058-956a-204e68242465.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2628_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2628_1_PB_WBC_C3_KHS5U_L13301; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a821167a-ef92-45eb-b5b8-b8ecb5f2561e

The open-access MAF lists 150 somatic variants for this specimen: 58 protein-altering or splice-affecting, 23 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 34, Silent 23, Intron 16, 3'Flank 6, 5'Flank 6, 5'UTR 5, Nonsense Mutation 4, RNA 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1397391819; called by muse, mutect2, varscan2
- ADAMTS7 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs111544126; called by muse, mutect2
- ANKRD30A | c.1694C>A p.S565Y (on ENST00000611781; = p.S509Y on NM_052997.2) | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs879174134, COSV64616386; called by muse, mutect2, varscan2
- ANTXRL | c.1141A>G p.K381E | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs1401641781; called by muse, mutect2, varscan2
- CACNB4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1023200310, COSV52390628; called by muse, mutect2, varscan2
- CHM | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63303198; called by muse, mutect2
- CXCR4 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs774186681; called by muse, mutect2, varscan2
- DUSP2 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 128/198 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1261249430; called by muse, mutect2, varscan2
- ENO2 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1245908131, COSV57545309; called by muse, mutect2, varscan2
- EPC1 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs778041123; called by muse, mutect2, varscan2
- ESS2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1322065209; called by muse, mutect2, varscan2
- EYA1 | c.1549T>G p.L517V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV58156566; called by muse, mutect2, varscan2
- FNTB | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs776308370; called by muse, mutect2, varscan2
- IGHV2-70 | c.191del p.K64Rfs*21 | Frame Shift Del (DEL) | VAF 46/58 reads (79%) | catalogued as rs763261850; called by pindel, varscan2
- IGHV4-34 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs587665321; called by muse, mutect2, varscan2
- LAMA1 | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as rs373498964; called by muse, mutect2, varscan2
- LENG8 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs772866105, COSV100458328; called by muse, mutect2
- MLH3 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as rs927878214; called by muse, mutect2, varscan2
- NOC4L | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as rs753351919; called by muse, mutect2, varscan2
- PIGN | c.2703G>A p.M901I | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV62948894; called by muse, mutect2
- PPL | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs1299064912; called by muse, mutect2, varscan2
- PPP4R1 | c.2038C>T p.R680* (on ENST00000400556 / NM_001042388.3; = p.R663* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 79/148 reads (53%) | catalogued as rs776245392, COSV53281685; called by muse, mutect2, varscan2
- RADIL | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.325); catalogued as rs774115748, COSV67651060; called by muse, mutect2, varscan2
- RGMA | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756255260, COSV61237415; called by muse, mutect2
- STYXL2 | c.1373A>G p.N458S | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760051518; called by muse, mutect2, varscan2
- TBX18 | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs941502769; called by muse, mutect2
- TXLNA | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285280917, COSV101009885; called by muse, mutect2
- ZNF366 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 167/228 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as rs770570348; called by muse, mutect2, varscan2
- ZNF652 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1192623979, COSV62947997; called by muse, mutect2
- ZSWIM6 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs963100061; called by muse, mutect2
- ADGRE1 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- AXIN2 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- BCL7A | c.91T>G p.W31G | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.31); called by muse, varscan2
- CFAP97 | c.215A>C p.N72T | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL6A5 | c.1241A>G p.Q414R | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCLK2 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DDX60L | c.183T>G p.N61K | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- FAM234B | c.1825T>G p.F609V | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- FAT4 | c.4407T>G p.F1469L | Missense Mutation (SNP) | VAF 129/209 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GLP1R | c.1028C>A p.T343K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- HMCN1 | c.8407G>A p.A2803T | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV2-70 | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 64/67 reads (96%) | called by muse, varscan2
- LGALS12 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- LRTM1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MITF | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, varscan2
- NCDN | c.-36+6C>T | Splice Region (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- OR56A3 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 305/440 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PIH1D2 | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2
- PIK3R6 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- SAMD11 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC24A2 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPRYD3 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2
- THNSL2 | c.908_909dup p.E304Lfs*34 | Frame Shift Ins (INS) | VAF 30/174 reads (17%) | called by mutect2, varscan2
- USP15 | c.2530A>G p.M844V (on ENST00000280377 / NM_001351159.2; = p.M815V on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2
- ZFP90 | c.1768T>G p.F590V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF330 | c.394T>C p.C132R | Missense Mutation (SNP) | VAF 15/283 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF440 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- ZNF521 | c.2747G>A p.S916N | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.313); called by muse, mutect2
- ARFGAP2 | c.825T>C p.R275= | Silent (SNP) | VAF 54/228 reads (24%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.702A>G p.K234= | Silent (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- CDH22 | c.1470G>C p.L490= | Silent (SNP) | VAF 58/151 reads (38%) | called by muse, mutect2, varscan2
- CLDN25 | c.558G>A p.S186= | Silent (SNP) | VAF 192/261 reads (74%) | catalogued as rs751679089; called by muse, mutect2, varscan2
- COL22A1 | c.4803C>T p.P1601= | Silent (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- GBP7 | c.1623T>C p.Y541= | Silent (SNP) | VAF 11/212 reads (5%) | catalogued as rs1454947255; called by muse, mutect2
- GRM4 | c.60C>T p.L20= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as COSV65217723; called by muse, mutect2, varscan2
- H1-2 | c.282G>C p.V94= | Silent (SNP) | VAF 62/184 reads (34%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.123C>T p.C41= | Silent (SNP) | VAF 54/58 reads (93%) | catalogued as rs377265996; called by muse, varscan2
- IGLV3-1 | c.216G>A p.R72= | Silent (SNP) | VAF 69/128 reads (54%) | catalogued as rs374319890; called by muse, varscan2
- IMPG2 | c.852A>G p.L284= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- LAMA5 | c.5634C>T p.G1878= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as rs143810549; called by muse, mutect2, varscan2
- MAGEA6 | c.423A>C p.G141= | Silent (SNP) | VAF 102/109 reads (94%) | called by muse, mutect2, varscan2
- MELK | c.501A>C p.T167= | Silent (SNP) | VAF 117/175 reads (67%) | called by muse, varscan2
- MRPL37 | c.459C>T p.C153= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs370161335; called by muse, mutect2, varscan2
- OR56A4 | c.1068G>A p.Q356= | Silent (SNP) | VAF 75/267 reads (28%) | called by muse, mutect2, varscan2
- P2RX5 | c.103C>T p.L35= | Silent (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- PCDH8 | c.1881C>T p.T627= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs1390257559, COSV58815515; called by muse, mutect2, varscan2
- PI4KA | c.4872C>T p.F1624= | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- SGPL1 | c.1350C>T p.V450= | Silent (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- TRAJ33 | c.12C>T p.N4= | Silent (SNP) | VAF 102/173 reads (59%) | called by muse, mutect2, varscan2
- TTLL7 | c.2106A>G p.E702= | Silent (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- ZNF440 | c.1056G>C p.V352= | Silent (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- ABHD17C | c.*213T>C | 3'UTR (SNP) | VAF 90/168 reads (54%) | called by muse, mutect2, varscan2
- AGPS | c.*3041T>C | 3'UTR (SNP) | VAF 42/110 reads (38%) | catalogued as rs1278720612; called by muse, mutect2, varscan2
- ARHGEF10L | c.3185-15C>T | Intron (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99394165; called by muse, mutect2, varscan2
- B3GNT2 | c.*287A>T | 3'UTR (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- BDKRB2 | c.*1327T>C | 3'UTR (SNP) | VAF 62/112 reads (55%) | called by muse, mutect2, varscan2
- BMP6 | c.*1215A>G | 3'UTR (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- BTG1 | c.-170A>T | 5'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- CADM1 | c.*1239A>G | 3'UTR (SNP) | VAF 130/173 reads (75%) | called by muse, mutect2, varscan2
- CBL | c.*948G>A | 3'UTR (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
- CNPY1 | c.*1395T>C | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- COPS5 | c.144-1058A>G | Intron (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- COX7A2L | c.-49T>C | 5'UTR (SNP) | VAF 82/221 reads (37%) | called by muse, mutect2, varscan2
- CPA1 | c.788-24G>A | Intron (SNP) | VAF 19/23 reads (83%) | catalogued as rs782150811; called by muse, varscan2
- CTSL3P | n.230A>C | RNA (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- CXCR4 | c.*166dup | 3'UTR (INS) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- D2HGDH | c.854-809A>G | Intron (SNP) | VAF 244/389 reads (63%) | called by muse, mutect2, varscan2
- DDN | c.210-21G>C | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- DNAJC6 | c.22+44964G>A | Intron (SNP) | VAF 11/36 reads (31%) | catalogued as rs1391601157, COSV54780596; called by muse, mutect2, varscan2
- ELFN2 | c.*3232C>T | 3'UTR (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- EP300 | c.-178C>T | 5'UTR (SNP) | VAF 134/302 reads (44%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1669-3325C>T | Intron (SNP) | VAF 72/144 reads (50%) | catalogued as rs772051461; called by muse, mutect2, varscan2
- FAM13B | c.*351T>G | 3'UTR (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- FAM98B | chr15:38486158 A>C | 3'Flank (SNP) | VAF 59/145 reads (41%) | called by muse, mutect2, varscan2
- FECH | c.*1979C>G | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- GEN1 | c.*2801C>T | 3'UTR (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- GNPTAB | c.1408+111G>T | Intron (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- GTF2H3 | chr12:123633786 G>A | 5'Flank (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- HES6 | chr2:238233629 G>A | 3'Flank (SNP) | VAF 129/373 reads (35%) | catalogued as rs1338185227; called by muse, mutect2, varscan2
- IL17RD | c.*3489A>G | 3'UTR (SNP) | VAF 51/98 reads (52%) | called by muse, mutect2, varscan2
- KCND3 | chr1:111775565 C>A | 3'Flank (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.-204G>A | 5'UTR (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- KLRC3 | c.*204T>C | 3'UTR (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- KSR1 | c.986-47C>T | Intron (SNP) | VAF 20/321 reads (6%) | catalogued as rs1261316678; called by muse, mutect2
- LAMC3 | c.*841A>G | 3'UTR (SNP) | VAF 114/188 reads (61%) | called by muse, mutect2, varscan2
- LINC02873 | n.1523T>G | RNA (SNP) | VAF 87/124 reads (70%) | called by muse, mutect2, varscan2
- MASP1 | c.1090+2889G>A | Intron (SNP) | VAF 198/353 reads (56%) | catalogued as rs773974562, COSV51457261; called by muse, mutect2, varscan2
- MDFIC | c.494-1185A>G | Intron (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- MIPOL1 | c.*1345A>T | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851183 G>C | 5'Flank (SNP) | VAF 77/230 reads (33%) | catalogued as rs771349600; called by muse, varscan2
- MIR5195 | chr14:106851256 T>A | 5'Flank (SNP) | VAF 72/214 reads (34%) | catalogued as rs749956333; called by muse, varscan2
- MRPL28 | c.288+144G>A | Intron (SNP) | VAF 18/223 reads (8%) | called by muse, mutect2
- NIBAN2 | c.*486G>C | 3'UTR (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- NQO1 | c.*1091C>G | 3'UTR (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- NTRK3 | c.*8765A>C | 3'UTR (SNP) | VAF 68/143 reads (48%) | called by muse, mutect2, varscan2
- NTRK3 | chr15:87874018 C>T | 3'Flank (SNP) | VAF 10/173 reads (6%) | catalogued as rs1432604798; called by muse, mutect2
- OLIG2 | c.-504A>T | 5'UTR (SNP) | VAF 64/233 reads (27%) | called by muse, mutect2, varscan2
- OPCML | c.*2521T>G | 3'UTR (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- OTUD4 | c.*1031A>G | 3'UTR (SNP) | VAF 91/262 reads (35%) | called by muse, mutect2, varscan2
- PARP15 | c.*1244G>T | 3'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- PDHX | chr11:34916340 G>A | 5'Flank (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- PIGK | c.*431T>C | 3'UTR (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- PPP1R12B | c.*5568G>A | 3'UTR (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- PSD3 | c.*4244G>A | 3'UTR (SNP) | VAF 17/41 reads (41%) | catalogued as rs543479749; called by muse, mutect2, varscan2
- RAB3IP | c.*5818A>G | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- RASGRP2 | c.-71-961G>T | Intron (SNP) | VAF 20/344 reads (6%) | catalogued as rs1196784155; called by muse, mutect2
- RCAN2 | c.*1692T>C | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- RRP15 | c.*5996A>G | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- S100A7A | chr1:153420952 G>C | 3'Flank (SNP) | VAF 11/261 reads (4%) | called by muse, mutect2
- SEC24D | c.*381A>G | 3'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- SELP | c.2408-23T>G | Intron (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20317093 A>C | 3'Flank (SNP) | VAF 51/94 reads (54%) | called by muse, mutect2, varscan2
- STPG2 | c.*3541T>G | 3'UTR (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- TEPP | c.688-71T>A | Intron (SNP) | VAF 9/135 reads (7%) | called by muse, mutect2
- UBC | chr12:124914923 del G | 5'Flank (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- UHMK1 | c.*6335T>C | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- USP25 | c.780+37G>A | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ZNF57 | chr19:2896724 T>A | 5'Flank (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- ZNF717 | c.*813A>C | 3'UTR (SNP) | VAF 60/106 reads (57%) | called by muse, mutect2, varscan2
- ZNF808 | c.*63T>C | 3'UTR (SNP) | VAF 66/548 reads (12%) | called by muse, mutect2, varscan2
